TARGET case TARGET-40-PALKGN — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/321e3803-c15c-5467-81d4-2321036f6a35

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.3; Tissue or organ of origin: Short bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 16.9 years (6,190 days); Year of diagnosis: 2002; Metastasis at diagnosis: No Metastasis; Days to last follow up: 2,122 days (5.8 years).
   Treatment given: Protocol identifier: P9851.

Follow-up (1 entry)
- Days to follow up: 2,122 days (5.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,122; Year of follow up: 2007.

Biospecimens (2 samples)
- Sample TARGET-40-PALKGN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-40-PALKGN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2122
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Foot NOS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PALKGN-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 94
- % Normal: Top from Biopsy: 2
- % Stroma: Top from Biopsy: 2
- % Necrosis: Top from Biopsy: 2
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 95
- % Normal: Bottom from Biopsy: 3
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 2
- PASS/FAIL: pass
